Somatic mutation profile of tumor specimen TCGA-HV-A5A4-01A (aliquot TCGA-HV-A5A4-01A-11D-A26I-08) from TCGA case TCGA-HV-A5A4, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Tail of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 72.0 years (26,311 days).
Specimen TCGA-HV-A5A4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67c9089c-8f25-4c9a-941a-07fc5bb04b46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HV-A5A4-10A (Blood Derived Normal), aliquot TCGA-HV-A5A4-10A-01D-A26I-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b533ee95-4729-46cf-bfc4-f0dd5bef1f07

The open-access MAF lists 42 somatic variants for this specimen: 32 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 9, Nonsense Mutation 2, Frame Shift Del 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AQP10 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 586/1477 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.865); catalogued as rs778846975, COSV61474642; called by muse, mutect2, varscan2
- ASIC3 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 92/407 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as rs150462572; called by muse, mutect2, varscan2
- BRD2 | c.763C>T p.H255Y | Missense Mutation (SNP) | VAF 162/624 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.082); catalogued as COSV100875582; called by muse, mutect2, varscan2
- CACNA1B | c.3151G>A p.V1051M | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.763); catalogued as COSV99495676; called by muse, mutect2
- CACNA1H | c.6965G>A p.R2322Q | Missense Mutation (SNP) | VAF 152/555 reads (27%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs1468102052, COSV52352905; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP3A5 | c.1022A>G p.N341S | Missense Mutation (SNP) | VAF 220/711 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as rs780728042, COSV99769558; called by muse, mutect2, varscan2
- DISP3 | c.3977C>T p.T1326M | Missense Mutation (SNP) | VAF 112/390 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779449261, COSV53837267; called by muse, mutect2, varscan2
- DKK2 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 201/789 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs539488952, COSV53393778; called by muse, mutect2, varscan2
- DOCK2 | c.5439C>A p.S1813R | Missense Mutation (SNP) | VAF 25/271 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV99910699; called by muse, mutect2
- FYCO1 | c.2792A>G p.Q931R | Missense Mutation (SNP) | VAF 53/506 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV99945275; called by muse, mutect2, varscan2
- GAA | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 63/236 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as rs770021831, COSV100162997; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GFAP | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 94/414 reads (23%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.979); catalogued as rs760982722, COSV99493099; called by muse, mutect2, varscan2
- KLK2 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 90/362 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100319877; called by muse, mutect2, varscan2
- MAGI2 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 196/644 reads (30%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.999); catalogued as rs762606410, COSV100833411; called by muse, mutect2, varscan2
- PDCD4 | c.829A>G p.T277A | Missense Mutation (SNP) | VAF 322/1065 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99700802; called by muse, mutect2, varscan2
- PDGFRB | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 110/481 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV99940273; called by muse, mutect2, varscan2
- PDZRN3 | c.1939C>T p.R647C | Missense Mutation (SNP) | VAF 238/798 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs746378403, COSV55193847, COSV55195895, COSV55201867; called by muse, mutect2, varscan2
- PES1 | c.1502A>G p.E501G | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100073014; called by muse, mutect2, varscan2
- PLIN4 | c.655G>A p.G219S (on ENST00000301286; = p.G234S on NM_001367868.2) | Missense Mutation (SNP) | VAF 286/1102 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs570323479, COSV56691904; called by muse, mutect2, varscan2
- PRKCD | c.798G>T p.M266I | Missense Mutation (SNP) | VAF 108/509 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.093); catalogued as COSV100387725; called by muse, mutect2, varscan2
- RNF213 | c.2503A>T p.I835F | Missense Mutation (SNP) | VAF 161/655 reads (25%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.864); catalogued as COSV100173173; called by muse, mutect2, varscan2
- RUBCNL | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 77/333 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs764655857, COSV100528893; called by muse, mutect2, varscan2
- SMAD4 | c.1558G>T p.E520* | Nonsense Mutation (SNP) | VAF 126/339 reads (37%) | catalogued as CM1410464, COSV61685467; called by muse, mutect2, varscan2
- STXBP5L | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 77/250 reads (31%) | catalogued as COSV99872501; called by muse, mutect2, varscan2
- TNFAIP8L2 | c.92T>C p.I31T | Missense Mutation (SNP) | VAF 230/539 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as rs768943835, COSV100925298; called by muse, mutect2, varscan2
- TNRC18 | c.4107G>T p.E1369D | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.388); catalogued as COSV101269575; called by muse, mutect2
- TRADD | c.463C>A p.L155M | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV99263430, COSV99263487; called by muse, mutect2, varscan2
- TTN | c.14376C>G p.F4792L (on ENST00000591111; = p.F3865L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 157/657 reads (24%) | PolyPhen benign (0.006); catalogued as COSV100598598; called by muse, mutect2, varscan2
- UMOD | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 71/280 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs141355380, COSV100207845; called by muse, mutect2, varscan2
- KMT2C | c.11714del p.P3905Lfs*29 | Frame Shift Del (DEL) | VAF 131/612 reads (21%) | called by mutect2, pindel, varscan2
- PLXNB2 | c.4557_4563dup p.T1522Gfs*154 | Frame Shift Ins (INS) | VAF 21/119 reads (18%) | called by mutect2, varscan2
- ST8SIA6 | c.942del p.G315Vfs*2 | Frame Shift Del (DEL) | VAF 424/1532 reads (28%) | called by mutect2, varscan2
- APBB1 | c.246G>A p.T82= | Silent (SNP) | VAF 499/1710 reads (29%) | catalogued as rs1186971924, COSV100193685, COSV54976748; called by muse, mutect2, varscan2
- BACH2 | c.1290C>T p.S430= | Silent (SNP) | VAF 81/374 reads (22%) | catalogued as rs930336992, COSV99998353; called by muse, mutect2, varscan2
- DCST1 | c.165C>T p.G55= | Silent (SNP) | VAF 182/1104 reads (16%) | catalogued as rs1212448584, COSV55051611; called by mutect2, varscan2
- IQCH | c.264C>G p.S88= | Silent (SNP) | VAF 72/232 reads (31%) | catalogued as COSV100245491; called by muse, mutect2, varscan2
- NOL8 | c.939G>A p.A313= | Silent (SNP) | VAF 47/150 reads (31%) | catalogued as rs373089019; called by muse, varscan2
- PCDHB16 | c.1899C>A p.R633= | Silent (SNP) | VAF 53/467 reads (11%) | catalogued as rs782450382, COSV53359682, COSV53371657; called by muse, mutect2, varscan2
- PEG3 | c.2430C>T p.F810= | Silent (SNP) | VAF 305/1131 reads (27%) | catalogued as rs1240769382, COSV55626829; called by muse, mutect2, varscan2
- RTL4 | c.15G>A p.T5= | Silent (SNP) | VAF 215/869 reads (25%) | catalogued as rs774074048, COSV61207080; called by muse, mutect2, varscan2
- VGLL1 | c.63G>A p.T21= | Silent (SNP) | VAF 213/742 reads (29%) | catalogued as rs747431633, COSV101034660, COSV65703146; called by muse, mutect2, varscan2
- DOCK8 | c.53+363C>T | Intron (SNP) | VAF 96/364 reads (26%) | catalogued as COSV101213626; called by muse, mutect2, varscan2
